Surgical pathology report (de-identified scan), TCGA case TCGA-85-8479, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8479-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology

	ID	Gross Description	Microscopic Description	Diagnosis Details
		Lower lobe, slightly increased in volume, with a white, intrabronchial tumoral structure of 1/2/1 cm in diameter, almost completely obstructed, with budding surface.	TUMOR FRAGMENT: Bronchopulmonary neoplasm of the spinocellular epidermoid carcinoma type without keratinization, G2, with papillary pattern, with monomorphous cellularity, nuclear atypias and isolated atypical mitoses, with hotbeds of necrosis and abundant fibrous-inflammatory stroma. RETROSTENOTIC PARENCHYMA: Pulmonary parenchyma with fibrin-leukocytic alveolitis. INTERLOBAR SPUR: Without tumoral aspect. INTERLOBAR LYMPH NODE: No metastases. LYMPH NODE STATION VII: No metastases. SUBAORTIC LYMPH NODE: No metastases. LYMPH NODE STATION VII: No metastases. PARAAORTIC LYMPH NODE:	

[page 2 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 2 x 1 x 1 cm Histologic type: Papillary squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Tumor in main bronchus Other tumor nodules: Not specified Lymph nodes: 0/7 positive for metastasis (St.11,7,6,5 0/7) Lymphatic invasion: Present Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

OpenClinica ID

[page 3 of 3]
Excision date

Laterality

Left- lower

Source: NCI Genomic Data Commons file c6d4209a-6057-404a-830c-6512919b8811 (TCGA-85-8479.815090DD-0F5F-4D63-BD1F-E8BD11EB99DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).